Somatic mutation profile of tumor specimen TCGA-MZ-A5BI-01A (aliquot TCGA-MZ-A5BI-01A-31D-A34J-08) from TCGA case TCGA-MZ-A5BI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Age at diagnosis: 53.4 years (19,500 days).
Specimen TCGA-MZ-A5BI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f96e23f-eca5-4105-a3de-02d84306d90e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MZ-A5BI-10C (Blood Derived Normal), aliquot TCGA-MZ-A5BI-10C-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e84ed2c-6537-48ff-aa33-4974b2a2f359

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB7 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV53723803; called by muse, mutect2, varscan2
- ADGRL1 | c.2705A>G p.N902S (on ENST00000340736 / NM_001008701.3; = p.N897S on NM_014921.5) | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.047); catalogued as rs781333888, COSV61566793; called by muse, mutect2
- ALDH1A3 | c.591T>G p.C197W | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320417; called by muse, mutect2, varscan2
- CACNG7 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781125638, COSV55816552; called by muse, mutect2, varscan2
- HPS6 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.98); catalogued as COSV100154882; called by muse, varscan2
- HPS6 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.439); catalogued as rs1450079645, COSV100154884; called by muse, varscan2
- IFT122 | c.1199G>A p.R400Q (on ENST00000348417 / NM_052989.3; = p.R341Q on NM_018262.4) | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1405512091, COSV99959334; called by muse, mutect2
- INPP5A | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.102); catalogued as rs966927613, COSV61248375; called by muse, mutect2, varscan2
- KIF27 | c.595C>G p.Q199E | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs921525533, COSV52826714; called by muse, mutect2, varscan2
- MTSS1 | c.889T>G p.S297A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.345); catalogued as COSV100274912; called by muse, varscan2
- MYNN | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62991041; called by muse, mutect2
- NFKBIA | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99395157; called by muse, mutect2, varscan2
- NRDC | c.2752G>C p.E918Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.048); catalogued as COSV100703398, COSV61403096; called by muse, mutect2, varscan2
- OR10K1 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193283, COSV99193580; called by muse, mutect2
- RELN | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58997745; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1564901245, COSV104376108, COSV99541605; called by muse, mutect2, varscan2
- SHPRH | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV51610529; called by muse, mutect2, varscan2
- SPRR2E | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 93/428 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV100907437; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2584A>T p.I862F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99691631; called by muse, mutect2, varscan2
- WDR1 | c.1198G>A p.G400R (on ENST00000382452; = p.G260R on NM_005112.5) | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.177); catalogued as rs765718599, COSV66723880; ClinVar: uncertain significance; called by muse, mutect2
- ZNF562 | c.517C>G p.Q173E (on ENST00000453372 / NM_001130032.2; = p.Q101E on NM_017656.4) | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99530702; called by muse, mutect2, varscan2
- ZNF646 | c.4490C>T p.P1497L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99762330; called by muse, mutect2, varscan2
- GPX1 | c.482_507del p.A161Gfs*? | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel
- MGAT1 | c.893_917del p.R298Lfs*7 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- ANXA13 | c.867G>A p.E289= | Silent (SNP) | VAF 68/332 reads (20%) | catalogued as COSV99146130; called by muse, mutect2, varscan2
- NAALADL2 | c.1779C>T p.Y593= | Silent (SNP) | VAF 44/314 reads (14%) | catalogued as rs368948927; called by muse, mutect2, varscan2
- NPY2R | c.570G>A p.S190= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs375788979, COSV100279426; called by muse, mutect2, varscan2
- NRXN1 | c.156C>T p.S52= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV68039053; called by muse, mutect2, varscan2
- POFUT1 | c.192C>T p.T64= | Silent (SNP) | VAF 87/206 reads (42%) | catalogued as COSV55788428; called by muse, mutect2, varscan2
- SRGAP2 | c.1444C>A p.R482= (on ENST00000624873 / NM_001170637.4; = p.R483= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99832867; called by muse, mutect2, varscan2
- TEP1 | c.3552C>T p.A1184= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99402450; called by muse, mutect2, varscan2
- WDR45B | c.165C>T p.G55= | Silent (SNP) | VAF 23/223 reads (10%) | catalogued as COSV66409611; called by muse, mutect2, varscan2
